Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3602, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3602-01A (Primary Tumor).

Diagnosis:

Resected colon and rectum show tumor-free oral, aboral and perirectal resection margins, including an ulcerated, moderately differentiated adenocarcinoma with infiltration of the perimuscular fatty tissue and several regional lymph node metastases (G2, pT3, pN2, 5/31 L1 V0, local R0).

Source: NCI Genomic Data Commons file 617ee4d9-4681-4f93-b1ad-9d89611d6e34 (TCGA-AG-3602.57DCFF98-D762-4366-9FF4-BDA7A6B45AB4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).